Somatic mutation profile of tumor specimen TCGA-06-0152-01A (aliquot TCGA-06-0152-01A-02D-1492-08) from TCGA case TCGA-06-0152, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.0 years (24,844 days).
Specimen TCGA-06-0152-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a4f05cb-0f7a-405f-8bbf-e86e01b5e9a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0152-10A (Blood Derived Normal), aliquot TCGA-06-0152-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6f474a2-2efd-4097-aaa8-86cf9becf5c4

The open-access MAF lists 58 somatic variants for this specimen: 45 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 38, Silent 13, Nonsense Mutation 3, Frame Shift Del 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AIDA | c.291C>G p.I97M | Missense Mutation (SNP) | VAF 256/327 reads (78%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as COSV60663434; called by muse, varscan2
- ALPK3 | c.2234C>A p.A745E | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51931683; called by muse, mutect2, varscan2
- CACNA1I | c.5740G>A p.V1914I | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs752733821, COSV60804081; called by muse, mutect2, varscan2
- CCDC33 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV58349692; called by muse, mutect2, varscan2
- CD8A | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1427820128, COSV52156884; called by muse, mutect2, varscan2
- CLCN1 | c.1457C>G p.P486R | Missense Mutation (SNP) | VAF 62/458 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58368604; called by muse, mutect2, varscan2
- DIMT1 | c.897del p.R300Dfs*29 | Frame Shift Del (DEL) | VAF 81/254 reads (32%) | catalogued as COSV52235192; called by mutect2, pindel, varscan2
- DOCK1 | c.4993G>T p.D1665Y | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV54734470; called by muse, mutect2, varscan2
- DOCK7 | c.3932C>G p.S1311* (on ENST00000635253 / NM_001367561.1; = p.S1280* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 22/197 reads (11%) | catalogued as COSV52000635; called by muse, mutect2, varscan2
- ENO3 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 104/244 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as rs773760593, COSV52776709; called by muse, mutect2, varscan2
- FEZ2 | c.468T>G p.D156E | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs772834464, COSV59906284; called by muse, mutect2, varscan2
- FILIP1 | c.923C>A p.S308* | Nonsense Mutation (SNP) | VAF 65/195 reads (33%) | catalogued as COSV52725951, COSV52735038; called by muse, mutect2, varscan2
- GNAT3 | c.814del p.D272Ifs*7 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | catalogued as COSV68070054; called by mutect2, varscan2
- GPR148 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV59307929; called by muse, mutect2, varscan2
- GRM4 | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs561013910, COSV65211913; called by muse, mutect2, varscan2
- JCAD | c.3670C>G p.P1224A | Missense Mutation (SNP) | VAF 128/198 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.747); catalogued as COSV64758741; called by muse, mutect2, varscan2
- KCNG1 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1190416165, COSV65368610; called by muse, mutect2
- KEL | c.560C>A p.S187Y | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.355); catalogued as COSV62334102, COSV62336854; called by muse, mutect2, varscan2
- LRBA | c.2729G>A p.R910H | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1199894762, COSV63952275, COSV63963465; called by muse, mutect2, varscan2
- MTUS2 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV70915295; called by muse, mutect2, varscan2
- MUC16 | c.19457T>C p.L6486S | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV67455605; called by muse, mutect2, varscan2
- NELL1 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.658); catalogued as rs150066751; called by muse, mutect2, varscan2
- PACS1 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.641); catalogued as COSV57697095; called by muse, mutect2, varscan2
- PCDHGB3 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV53920507; called by muse, mutect2, varscan2
- PEX11A | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 213/593 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55583164; called by muse, mutect2, varscan2
- PGM5 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 104/300 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs141668530; called by muse, mutect2, varscan2
- PREX1 | c.4810C>T p.R1604W | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447178153, COSV64249860; called by muse, mutect2, varscan2
- PRMT8 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 125/328 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV54212860; called by muse, mutect2, varscan2
- PSG7 | c.1243G>T p.D415Y | Missense Mutation (SNP) | VAF 169/423 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.601); catalogued as rs773962473, COSV68444724; called by muse, mutect2, varscan2
- RELN | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 42/241 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1187393292, COSV58993482; called by muse, mutect2, varscan2
- RYR3 | c.9354G>T p.E3118D (on ENST00000389232; = p.E3119D on NM_001036.6) | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV66782864; called by muse, mutect2, varscan2
- SEC63 | c.981A>C p.K327N | Missense Mutation (SNP) | VAF 140/322 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV64599121; called by muse, mutect2, varscan2
- SERPINB5 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs145559318, COSV66975210; called by muse, mutect2, varscan2
- SIPA1L1 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 58/193 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62169293; called by muse, mutect2, varscan2
- SLC9C2 | c.1744T>G p.C582G | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62944703; called by muse, mutect2, varscan2
- SLITRK6 | c.118A>C p.K40Q | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV68389763; called by muse, mutect2, varscan2
- SSTR4 | c.832G>T p.V278L | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.048); catalogued as COSV54797581; called by muse, mutect2, varscan2
- TAX1BP3 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs747198869, COSV50440048; called by muse, mutect2, varscan2
- TMC4 | c.917A>C p.D306A (on ENST00000617472 / NM_001145303.3; = p.D300A on NM_144686.4) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as COSV56598829; called by muse, mutect2, varscan2
- TRIM55 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 55/123 reads (45%) | catalogued as COSV52544913; called by muse, mutect2, varscan2
- TYRO3 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1338476882, COSV55482078; called by muse, mutect2, varscan2
- ULK4 | c.971A>C p.K324T | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV57203968; called by muse, mutect2, varscan2
- USH1G | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.111); catalogued as COSV58881186; called by muse, mutect2, varscan2
- HMCN1 | c.6557dup p.N2186Kfs*16 | Frame Shift Ins (INS) | VAF 53/99 reads (54%) | called by mutect2, varscan2
- ZNF45 | c.1879del p.L627Ffs*67 | Frame Shift Del (DEL) | VAF 43/249 reads (17%) | called by mutect2, pindel, varscan2
- ADGRG6 | c.2674T>C p.L892= | Silent (SNP) | VAF 49/123 reads (40%) | catalogued as COSV51589133; called by muse, mutect2, varscan2
- DNAJC16 | c.1335A>C p.S445= | Silent (SNP) | VAF 129/196 reads (66%) | catalogued as COSV65448298; called by muse, mutect2, varscan2
- FAM181A | c.243C>T p.S81= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as rs369127722; called by muse, mutect2, varscan2
- FLT4 | c.2076C>T p.S692= | Silent (SNP) | VAF 46/114 reads (40%) | catalogued as COSV56103072; called by muse, mutect2, varscan2
- FOXJ1 | c.354G>T p.P118= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs1157058439, COSV53942956; called by muse, mutect2, varscan2
- GAREM1 | c.357C>T p.R119= | Silent (SNP) | VAF 115/307 reads (37%) | catalogued as rs775839313, COSV52507354; called by muse, mutect2, varscan2
- NLRP9 | c.807C>T p.S269= | Silent (SNP) | VAF 42/135 reads (31%) | catalogued as rs780877323, COSV60461356; called by muse, mutect2, varscan2
- OOEP | c.126G>A p.P42= | Silent (SNP) | VAF 58/198 reads (29%) | catalogued as rs1320168142, COSV64859084; called by muse, mutect2, varscan2
- OPN5 | c.657C>T p.Y219= | Silent (SNP) | VAF 66/203 reads (33%) | catalogued as rs375529102, COSV55245422; called by muse, mutect2, varscan2
- PLCB1 | c.231C>T p.H77= | Silent (SNP) | VAF 33/142 reads (23%) | catalogued as rs773937907, COSV62040242; ClinVar: likely benign; called by muse, mutect2, varscan2
- SERPINA11 | c.609G>A p.T203= | Silent (SNP) | VAF 80/215 reads (37%) | catalogued as rs757990411, COSV58241455; called by muse, mutect2, varscan2
- SOHLH1 | c.864G>A p.A288= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs764239665, COSV53681104; called by muse, mutect2, varscan2
- TMEM132D | c.1311C>T p.I437= | Silent (SNP) | VAF 53/134 reads (40%) | catalogued as COSV70599498; called by muse, mutect2, varscan2
